Somatic mutation profile of tumor specimen TCGA-A5-A0R7-01A (aliquot TCGA-A5-A0R7-01A-31D-A10B-09) from TCGA case TCGA-A5-A0R7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 55.4 years (20,250 days).
Specimen TCGA-A5-A0R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d55b33a-40b5-455e-8a93-43f9c5bbccc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0R7-10A (Blood Derived Normal), aliquot TCGA-A5-A0R7-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c39f9cc-e7c1-423f-bd70-25147c8d72f9

The open-access MAF lists 76 somatic variants for this specimen: 51 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 22, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1745+2del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 71/161 reads (44%) | hotspot (GDC flag); catalogued as COSV57137770; called by mutect2, pindel, varscan2
- PTEN | c.548dup p.N184Efs*6 | Frame Shift Ins (INS) | VAF 71/282 reads (25%) | catalogued as rs1554900593, COSV64296770; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCD2 | c.1386T>A p.S462R | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58054583; called by muse, mutect2
- ADD2 | c.2042A>T p.K681M | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV52469597; called by muse, mutect2
- ANKRD30A | c.188C>A p.T63N (on ENST00000611781; = p.T7N on NM_052997.2) | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.391); catalogued as COSV64619171; called by muse, mutect2
- BBOF1 | c.650A>C p.Q217P | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV67455600; called by muse, mutect2, varscan2
- BRWD3 | c.4189A>T p.I1397L | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV64752819; called by muse, mutect2
- C1QTNF5 | c.668C>G p.T223R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV60991340; called by muse, mutect2, varscan2
- CACNA1E | c.4615C>T p.R1539* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as COSV62414989; called by muse, mutect2, varscan2
- CEACAM7 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs782045514, COSV50074464; called by muse, mutect2, varscan2
- CEP170 | c.2348A>G p.Q783R | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as COSV60513939; called by muse, mutect2, varscan2
- CNPPD1 | c.236A>G p.K79R | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as COSV56088712; called by muse, mutect2
- CSMD1 | c.8830C>T p.R2944C (on ENST00000520002; = p.R2943C on NM_033225.6) | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1431976322, COSV59318142; called by muse, mutect2, varscan2
- CTAG2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV55994700, COSV55996639; called by muse, mutect2, varscan2
- DDX42 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV63791183; called by muse, mutect2, varscan2
- DLG1 | c.2237C>A p.T746K (on ENST00000419354 / NM_001290983.1; = p.T768K on NM_004087.2) | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58389884; called by muse, mutect2
- DLG2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54678972; called by muse, mutect2, varscan2
- DNAJC5B | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV52539543; called by muse, mutect2
- DPP9 | c.2008C>G p.L670V (on ENST00000598800; = p.L699V on NM_139159.5) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV53593981; called by muse, mutect2, varscan2
- ERAS | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1557032999, COSV54433356; called by muse, mutect2, varscan2
- GALNT15 | c.1500A>T p.E500D | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV60219421; called by muse, mutect2
- GBF1 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64148460; called by muse, mutect2
- HERC2 | c.7936C>G p.R2646G | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55337121, COSV55346193; called by muse, mutect2
- KALRN | c.6050T>C p.I2017T (on ENST00000360013 / NM_001024660.4; = p.I320T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV52263484; called by muse, mutect2
- KCNH4 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751569305, COSV52920746; called by muse, mutect2, varscan2
- KIAA1549 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54326093; called by muse, mutect2
- LRTM2 | c.317G>C p.R106P | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs766045075, COSV54564229; called by muse, mutect2, varscan2
- MED12 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61330639, COSV61353716; called by muse, mutect2, varscan2
- OSTC | c.431C>G p.P144R | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV104422627, COSV64232500; called by muse, mutect2, varscan2
- PCDHA12 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.082); catalogued as rs200698690, COSV56539607; called by muse, mutect2, varscan2
- PTEN | c.189_196dup p.K66Tfs*36 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | catalogued as CI110197; called by mutect2, varscan2
- R3HDM2 | c.2330G>A p.S777N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV61294444; called by muse, mutect2
- RPLP0 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs766132340, COSV56113874; called by muse, mutect2, varscan2
- RSPH6A | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV55574864, COSV99680221; called by muse, mutect2, varscan2
- SERINC2 | c.694G>A p.G232S (on ENST00000373709 / NM_178865.5; = p.G236S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs184672093, COSV65491629; called by muse, mutect2, varscan2
- SI | c.4292T>A p.L1431* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52297853; called by muse, mutect2, varscan2
- SLC12A6 | c.1138C>T p.R380C (on ENST00000354181 / NM_001365088.1; = p.R329C on NM_005135.2) | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs932047360, COSV51630969; called by muse, mutect2
- SMARCC1 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV54385701; called by muse, mutect2
- SSR1 | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV55204165; called by muse, mutect2
- TBX18 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs987207695, COSV63736139, COSV63737235; called by muse, mutect2, varscan2
- TFDP2 | c.320G>A p.R107Q (on ENST00000489671 / NM_001178139.2; = p.R46Q on NM_006286.5) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs776524764, COSV57710730; called by muse, mutect2, varscan2
- TJP3 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs147001701; called by mutect2, varscan2
- TP53 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 71/108 reads (66%) | catalogued as COSV52992944; called by mutect2, pindel, varscan2
- TRIM16 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV60888177; called by muse, mutect2
- UBAP2L | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs757610873, COSV55175647; called by muse, mutect2, varscan2
- UGT2B15 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV57736266; called by muse, mutect2, varscan2
- UNC5B | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs764059399, COSV58980780; called by muse, mutect2, varscan2
- ARHGAP32 | c.1139del p.N380Ifs*51 (on ENST00000310343 / NM_001378025.1; = p.N31Ifs*51 on NM_014715.4) | Frame Shift Del (DEL) | VAF 38/133 reads (29%) | called by mutect2, pindel, varscan2
- CNST | c.818+2dup p.X273_splice | Splice Site (INS) | VAF 63/240 reads (26%) | called by mutect2, pindel, varscan2
- KANK1 | c.3764_3767del p.A1255Vfs*41 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- TCP11 | c.1105T>G p.F369V (on ENST00000512012; = p.F307V on NM_018679.5) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); called by muse, mutect2
- C21orf62 | c.255G>A p.T85= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs200869965, COSV101212298, COSV66671786; called by muse, mutect2, varscan2
- CAPN5 | c.471C>T p.Y157= (on ENST00000456580; = p.Y117= on NM_004055.5) | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs746258458, COSV53690816; called by muse, mutect2, varscan2
- CHST1 | c.810G>A p.T270= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57325370; called by muse, mutect2, varscan2
- CLCF1 | c.141C>G p.T47= | Silent (SNP) | VAF 11/159 reads (7%) | catalogued as COSV56862412; called by muse, mutect2
- EGFR | c.813C>T p.N271= | Silent (SNP) | VAF 14/246 reads (6%) | catalogued as COSV51840268; called by muse, mutect2
- FRG2B | c.54C>A p.S18= | Silent (SNP) | VAF 116/1108 reads (10%) | catalogued as COSV71044058; called by muse, mutect2
- GRM3 | c.1056G>C p.R352= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV64476426, COSV64478548; called by muse, mutect2, varscan2
- HEATR4 | c.2061G>A p.A687= | Silent (SNP) | VAF 36/64 reads (56%) | catalogued as rs766767211, COSV58576792; called by muse, mutect2, varscan2
- HTR5A | c.363C>T p.D121= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs778025705, COSV55286591, COSV55286853; called by muse, mutect2, varscan2
- LCT | c.5506C>A p.R1836= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV51553068, COSV51556430; called by muse, mutect2, varscan2
- LEP | c.432G>A p.V144= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV58241663; called by muse, mutect2
- MAGED1 | c.27G>C p.A9= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV58516638; called by muse, mutect2
- NCOA7 | c.2121T>C p.F707= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV57659490; called by muse, mutect2, varscan2
- NUP214 | c.648G>A p.V216= | Silent (SNP) | VAF 8/187 reads (4%) | catalogued as COSV63912669; called by muse, mutect2
- OR2B3 | c.183C>T p.F61= | Silent (SNP) | VAF 8/147 reads (5%) | catalogued as COSV65850724, COSV65850737; called by muse, mutect2
- OR5T1 | c.837T>C p.T279= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV57302542, COSV57304590; called by muse, mutect2
- PTCD3 | c.1125T>C p.I375= | Silent (SNP) | VAF 10/327 reads (3%) | catalogued as COSV54482743; called by muse, mutect2
- RPL13A | c.55C>T p.L19= | Silent (SNP) | VAF 51/170 reads (30%) | catalogued as COSV52620719; called by muse, mutect2, varscan2
- SI | c.4291T>C p.L1431= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52297866; called by muse, mutect2, varscan2
- SMARCC2 | c.2596C>T p.L866= | Silent (SNP) | VAF 10/220 reads (5%) | catalogued as COSV57224136; called by muse, mutect2
- TIMP2 | c.357C>T p.D119= | Silent (SNP) | VAF 71/105 reads (68%) | catalogued as rs770056235, COSV53162802; called by muse, mutect2, varscan2
- ZFHX4 | c.2274G>A p.P758= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs917994744, COSV51491814; called by muse, mutect2, varscan2
- CCDC83 | c.794+1296C>T | Intron (SNP) | VAF 11/376 reads (3%) | catalogued as COSV99721742; called by muse, mutect2
- MIR381 | n.8A>G | RNA (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- OR2AK2 | c.-14T>C | 5'UTR (SNP) | VAF 14/116 reads (12%) | catalogued as COSV63559688; called by muse, mutect2, varscan2
